Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ABEA, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ABEA-TTM1-A (Metastatic).

[page 1 of 45]
Patient Information

Patient Name

Sex

DOB

Female

Results

NON-GYN CYTOLOGY / HISTOLOGY SPECIMEN

Collection Information

Collected: +3670

Entry Date

+3671

Result Narrative

PATHOLOGY DEPARTMENT

Patient Name:

Accession #:

Patient ID #:

Collected:

Address:

Room # PATIENT CARE

(Age: 40) F NS :

Physician(s):

Account#

Copy To:

FINAL DIAGNOSIS:

1. RIGHT AXILLARY NODE:

--Metastatic malignant melanoma.

Comment:

The tumor is confined to the lymph node and measures maximally 1.5 cm. in greatest dimension. Multifocal melanin pigment is identified.

2. RIGHT AXILLARY LYMPH NODES AND TISSUE:

Lymph Nodes: --Number of lymph nodes examined: 15

--Number of lymph nodes with metastasis: 0

Electronically Signed Out By

SPECIMEN(S) RECEIVED:

1: RIGHT AXILLARY NODE

2: RIGHT AXILLARY LYMPH NODES AND TISSUE

CLINICAL HISTORY:

Hx of melanoma

GROSS DESCRIPTION:

The specimen is submitted in two parts, part one is labeled "axillary node" and consists of a gray-tan glistening lymph node measuring 2.5 x 2.0 x 1.0 cm. Cut sections show a glassy gray-tan cut surface with focal black discoloration.

Part two is labeled "right axillary lymph nodes and tissue" and consists of fragments of fat aggregating 5.5 cm. Located are multiple pink-tan lymph nodes, the largest measuring 2.2 cm.

SLIDE TABLE:

A: multiple small lymph nodes

[page 2 of 45]
FROZEN SECTION DIAGNOSIS:

MICROSCOPIC DESCRIPTION:

ICD-9(s): 196.3 172.9

Authorizing Provider

[page 3 of 45]
- Record only one patient and protocol per transmittal sheet
- Ensure Patient ID and Protocol ID are recorded on each page of each item included
- Remove all patient identifiers or HIPAA protected information
- Ensure pages are in proper sequence (2-sided forms must be copied by site before faxing)
- Do not fax more than 50 pages in one submission
- Submit updated data with a new transmittal and new date
- Ensure updates to documents are initialed and dated

Refaxing

+6527

Date: [REDACTED]
(dd-mmm-yyyy)

Total # Pages Faxed: 43
(including transmittal)

Patient ID#: [REDACTED]

Site Name: [REDACTED]

NCI Site Code: [REDACTED]
(Example TX001)

Site Address: [REDACTED]

Completed By: [REDACTED]

Email address: [REDACTED]

Contact information will be used if [REDACTED] has questions or if data submission needs to be re-submitted with corrective action

Item(s) Attached (record only 1 item per row)	Number of Pages	Check only one visit per box	Check if Updated or re- submitted data
☐ : Supporting document		☐ : Registration/Baseline ☐ : Cycle _____ ☐ : Off Treatment ☐ : Other _____	☐
☐ : Memo/Note to File		☐ : Registration/Baseline ☐ : Cycle _____ ☐ : Off Treatment ☐ : Other _____	☐
☒ : Other Radiology Reports	43	☒ : Registration/Baseline ☐ : Cycle _____ ☐ : Off Treatment ☐ : Other _____	☒
☐ : Other _____		☐ : Registration/Baseline ☐ : Cycle _____ ☐ : Off Treatment ☐ : Other _____	☐

[REDACTED]

[REDACTED]

[page 4 of 45]
Results

CT CHEST WITHOUT CONTRAST (Accession#

Name:

CSN:

DOB:

Order Phys:

MR#/HAR:

Pt. Class:

Order:

Accession:

Admit Date:

+6422

CT CHEST WITHOUT CONTRAST

+6422

EXAM: CHEST CT:

INDICATION:

Dyspnea.

COMPARISON:

+5719

TECHNIQUE:

Helical CT of the chest was performed without intravenous contrast. Multiplanar reformatted images were obtained.

FINDINGS:

LUNGS AND AIRWAYS:

Unchanged bilateral basilar dependent ground-glass opacities. Right apical subpleural fibrosis and mild architectural distortion exhibit little change. Intrapulmonary lymphoid tissue along the left major fissure. No mass or consolidation. No endoluminal lesion.

PLEURAL SPACES:

The pleural spaces are normal.

HEART AND MEDIASTINUM:

The imaged portions of the thyroid gland are normal. No axillary, mediastinal, or obvious hilar lymphadenopathy. The heart is normal in size. No pericardial effusion. Normal-caliber thoracic aorta.

UPPER ABDOMEN:

Cholecystectomy.

SKELETAL STRUCTURES AND SOFT TISSUES:

Minimal rightward convexity curvature of the spine could be positional. No acute or healing fractures. No thoracic compression deformities. Breast implants.

[page 5 of 45]
[REDACTED]

IMPRESSION:

1. Minimal basilar dependent ground-glass opacities likely reflect dependent atelectasis. No consolidation or interstitial edema.
2. No intrathoracic lymphadenopathy.
3. Incidental findings as described.

Appropriate radiation dose reduction devices and/or manual techniques for appropriate moderation of exposure were utilized.

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[page 6 of 45]
Results CT CHEST WITH CONTRAST

WITH CONTRAST

RADIOLOGY CT REPORT

Name:

Address:

Telephone:

CSN:

HAR:

MR#:

Order:

DOB:

Pt. Class: Outpatient

ROOM:

Admit Date: +4260

Disch Date: +4260

Accession

CT CHEST WITH CONTRAST

+4260

CT CHEST WITH IV CONTRAST

HISTORY:

Melanoma.

FINDINGS:

There are 2 lung nodules identified in the right lower lobe; one is seen on image number 43 and the other is seen on image 46. Both measure 13 mm. A third nodule is seen medially in the right lower lobe on image number 29. It measures 9 mm and is most consistent with metastatic disease.

Fibrosis right apex is demonstrated. Possible fibrosis right lung base. No mediastinal or axillary adenopathy is seen. Previous right axillary surgery noted.

IMPRESSION:

1. Three right-sided lung nodules worrisome for metastatic disease.
2. Fibrosis right apex.
3. Fibrosis or pleural thickening or possibly atelectasis right lung base.

Appropriate radiation dose reduction devices and/or manual techniques for appropriate moderation of exposure were utilized.

[page 7 of 45]
[Redacted]

[Redacted]

Electronically Signed by [Redacted]
[Redacted]

+4273

[Redacted]

[Redacted]

[Redacted]

[Redacted]

4/2/24 11:05

[page 8 of 45]
Results

CT CHEST WITH CONTRAST

CT ABD/PELVIS

WITH CONTRAST

Name:

Address:

Telephone:

CSN:

HAR:

MR#:

Order:

DOB:

Pt. Class: Outpatient

ROOM:

Att. Phys:

Ord. Phys:

Insurance:

Admit Date: +4260

Disch Date: +4260

Accession:

CT ABD/PELVIS WITH CONTRAST

+4260

CT ABDOMEN AND PELVIS WITH INTRAVENOUS CONTRAST AND
ORAL CONTRAST

HISTORY:

Melanoma.

FINDINGS:

Lung bases right side nodules new from the previous examination. Liver and spleen are unremarkable. The gallbladder has been removed. Bilateral adrenal glands are normal. Left angiomyolipoma in the kidney is seen. Left low-dense lesion in the kidney is seen, unchanged. Right kidney is unremarkable. No paraortic or retroperitoneal adenopathy. No pelvic masses or adenopathy. No free fluid is seen.

IMPRESSION:

1. Angiomyolipoma left kidney.
2. Probable cyst left kidney.
3. Two nodules right lung base, new from previous examination with associated right basilar atelectasis.

Appropriate radiation dose reduction devices and/or manual techniques for appropriate moderation of exposure were utilized.

[page 9 of 45]
[REDACTED]

[REDACTED]

[REDACTED]

DD:
DT:

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[page 10 of 45]
Results

CT LOCALIZATION WITH BIOPSY (Accession# [REDACTED])

[REDACTED]

Name: [REDACTED]
Address: [REDACTED]
Telephone: [REDACTED]
CSN: [REDACTED]
HAR: [REDACTED]
MR#: [REDACTED]
Order: [REDACTED]
DOB: [REDACTED]
Pt. Class: Outpatient
ROOM: [REDACTED]
Att. Phys: [REDACTED]
Ord. Phys: [REDACTED]
Insurance: [REDACTED]

Admit Date: [REDACTED] +4272
Disch Date: [REDACTED] +4272
Accession [REDACTED]

CT LOCALIZATION WITH BIOPSY

+4272 [REDACTED] CT-GUIDED LUNG BIOPSY

HISTORY:

42-year-old woman with malignant melanoma has 2 lung nodules in the right lower lobe with increased uptake on FDG PET. Biopsy requested.

TECHNIQUE:

The patient was given conscious sedation with Versed and fentanyl with constant monitoring by the physician and nursing staff. Total sedation time was less than 30 minutes.

Limited 5 mm unenhanced images were obtained through the mid chest with the patient in a right lateral decubitus position. A route for biopsy was chosen. The overlying skin was prepped and draped in a sterile manner. 1% lidocaine was used for local anesthesia. Under CT guidance, a 19-gauge access needle was advanced to the posterior margin of the larger of the 2 nodules. Through this access needle, three 20-gauge core biopsy specimens were obtained and submitted to pathology in formalin. The needle was removed. Followup images were obtained. A sterile dressing was applied.

FINDINGS:

Limited CT images redemonstrate the 2 known right-sided pulmonary nodules in the right lower lobe. Subsequent images demonstrate the needle being advanced towards this lesion. Images following biopsy demonstrate a small amount of hemorrhage along the needle tract but no evidence of pneumothorax or other complication.

[page 11 of 45]
[REDACTED]

IMPRESSION:

Successful CT-guided lung biopsy as described above. A followup chest x-ray will be obtained in 3 hours.

Appropriate radiation dose reduction devices and/or manual techniques for appropriate moderation of exposure were utilized.

[REDACTED]

[REDACTED]

[page 12 of 45]
Results

CT CHEST WITH CONTRAST (Accession# [REDACTED])

CT ABD/PELVIS

WITH CONTRAST [REDACTED]

Admit Date: [REDACTED] +4420

Disch Date: [REDACTED] +4420

Accession [REDACTED]

CT ABD/PELVIS WITH CONTRAST

+4420

[REDACTED] CT ABDOMEN AND PELVIS WITH CONTRAST

HISTORY:

Melanoma.

FINDINGS:

Contrast-enhanced axial images of the abdomen and pelvis were obtained with comparison to [REDACTED] +4260

For findings regarding the lung bases and lower thorax, please see the patient's chest CT of the same date.

No acute bony abnormalities are identified. A stable small presumed bone island of the right ilium is evident. The aorta is not enlarged.

There are no new hepatic or splenic masses. A stable accessory splenule is observed. The gallbladder is surgically absent.

There are no focal gastric abnormalities. The adrenal glands, right kidney, and pancreas appear normal. A stable small angiomyolipoma of the superior pole of the left kidney is observed. A stable additional hypodensity of the anterior midpole of the left kidney is evident and is likely secondary to a small cortical cyst.

There are a few small stable appearing paraaortic lymph nodes without

[page 13 of 45]
[REDACTED]

— evidence of new or progressive intra-abdominal or pelvic adenopathy.
— The uterus and adnexal structures are without concerning abnormality.

— There is no evidence of free intra-abdominal fluid or air. No definite acute intra-abdominal inflammatory changes are identified. There is no evidence of bowel obstruction. The surrounding abdominal and pelvic soft tissues are without concerning abnormality.

IMPRESSION:

1. No acute intra-abdominal process.
2. No evidence of new or progressive intra-abdominal or pelvic adenopathy.
3. Stable left renal lesions as discussed above.
4. Additional findings as discussed above. Please also see the patient's chest CT of the same date.

Appropriate radiation dose reduction devices and/or manual techniques for appropriate moderation of exposure were utilized.

[REDACTED]

[REDACTED]

[REDACTED]

[page 14 of 45]
Results

CT CHEST WITH CONTRAST (Accession# [REDACTED])

CT ABD/PELVIS

WITH CONTRAST [REDACTED]

Name: [REDACTED]

Address: [REDACTED]

Telephone: [REDACTED]

CSN: [REDACTED]

HAR: [REDACTED]

MR#: [REDACTED]

Order: [REDACTED]

DOB: [REDACTED]

Pt. Class: Outpatient [REDACTED]

Admit Date: [REDACTED]

+4420

Disch Date: [REDACTED]

+4420

Accession: [REDACTED]

CT CHEST WITH CONTRAST

+4420

CT CHEST WITH CONTRAST

HISTORY:

Melanoma.

FINDINGS:

Contrast-enhanced axial images of the chest were obtained with comparison to [REDACTED] +4260

For findings regarding the upper abdomen, please see the patient's abdominal and pelvis CT of the same date.

No acute bony abnormalities are identified. A left subclavian Port-A-Cath is in place with its distal tip in the superior vena cava. The thoracic aorta is not enlarged.

The visualized portions of the thyroid gland appear normal. The heart is not enlarged and there is no evidence of a pericardial effusion. No new or progressive mediastinal or hilar adenopathy is identified. A stable approximately 10-mm soft tissue opacity of the right hilum is seen on series 2 image 23 and may be indicative of a lymph node. No left axillary adenopathy is observed. There is a postsurgical appearance of the right axilla with persistent, stable-appearing soft tissue thickening evident. The surrounding thoracic soft tissues are without concerning abnormality.

[page 15 of 45]
[REDACTED]

Tracheal air column is widely patent. No new endobronchial lesions are identified. There is a stable 3-mm nodule of the anterior left upper lobe on series 3 image 21. A 7-mm fissure-based nodule of the left lung on series 3 image 28 is better seen when compared to the prior exam possibly secondary to slice variation. A mild degree of left basilar atelectasis is noted. Stable consolidative changes of the right lung apex are observed and may be sequela of prior radiation therapy. Additionally, there is stable soft tissue thickening and pleural thickening of the periphery of the right lung base. There are no definite new right lung parenchymal nodules. Previously apparent nodular foci of the right lower lobe have largely resolved over the interim. There are no new or enlarged pulmonary parenchymal nodules. No pleural effusion is evident on the right or left. The remainder of the exam is unremarkable.

[REDACTED]

IMPRESSION:

1. Stable left lung nodularity as discussed above.
2. Interval resolution of previously apparent right lower lobe parenchymal nodules.
3. Presumed postradiation changes of the right lung apex and periphery of the right lung base.
4. No evidence of new or progressive mediastinal, hilar, or axillary adenopathy as discussed above.
5. Left subclavian Port-A-Cath.
6. Postoperative appearance of the right axilla.
7. Additional findings as discussed above.

Appropriate radiation dose reduction devices and/or manual techniques for appropriate moderation of exposure were utilized.

[REDACTED]

[REDACTED]

[page 16 of 45]
Results

**CT ABD PELVIS WITH CONTRAST (Accession# [REDACTED])
WITH CONTRAST [REDACTED]**

CT CHEST

Name: [REDACTED]

Address: [REDACTED]

Telephone: [REDACTED]

CSN: [REDACTED]

HAR: [REDACTED]

MR#: [REDACTED]

Order: [REDACTED]

DOB: [REDACTED]

Pt. Class: Outpatient [REDACTED]

ROOM: [REDACTED]

Admit Date: [REDACTED] +4531

Disch Date: [REDACTED]

Accession [REDACTED]

CT ABD PELVIS WITH CONTRAST

CT ABDOMEN AND PELVIS WITH CONTRAST;

HISTORY:

Malignant melanoma.

FINDINGS:

Contrast-enhanced axial images of the abdomen and pelvis were obtained with delayed and coronal reformatted images acquired. Comparison is made to [REDACTED] +4420

For findings regarding the lung bases and lower thorax, please see the patient's chest CT of the same date.

No definite acute bony abnormalities are identified. Small sclerotic foci in the right iliac wing and left ischium are likely indicative of bone islands. There is no evidence of aneurysm formation.

There are no new hepatic lesions. Stable borderline prominence of the spleen is evident without focal splenic mass. Accessory splenule formation is noted. The gallbladder is surgically absent.

There are no focal gastric abnormalities. The adrenal glands, right kidney, and pancreas appear normal. There is a stable 12-mm fat density lesion in the superior pole of the left kidney likely indicative of an angiomyolipoma. An additional stable cortical hypodensity of the

[page 17 of 45]
[REDACTED]

anterior midpole of the right kidney is observed. This is subcentimeter in size and is likely representative of a small cyst.

There are stable borderline-to-mildly prominent left paraaortic lymph nodes measuring up to 13 mm. No new or progressive intra-abdominal or pelvic adenopathy is identified. A few sigmoid diverticula are suggested. No definite uterine or adnexal mass is observed. A large colonic stool volume is evident. No free intra-abdominal fluid or air is apparent. There is no evidence of bowel wall thickening or bowel obstruction. Surrounding abdominal and pelvic soft tissues are without concerning abnormality.

IMPRESSION:

1. No acute intra-abdominal process with large colonic stool volume.
2. A few stable borderline-to-mildly enlarged left paraaortic lymph nodes without evidence of new or progressive intra-abdominal or pelvic adenopathy.
3. Status post cholecystectomy.
4. Stable left renal angiomyolipoma.
5. Additional findings as discussed above.

Appropriate radiation dose reduction devices and/or manual techniques for appropriate moderation of exposure were utilized.

[REDACTED]

[REDACTED]

[REDACTED]

[page 18 of 45]
[REDACTED]

Results

CT ABD PELVIS WITH CONTRAST (Accession# [REDACTED])
WITH CONTRAST

CT CHEST

[REDACTED]

Name:
Address:
Telephone:

Admit Date: [REDACTED] +4531

Disch Date: [REDACTED]

Accession [REDACTED]

CT CHEST WITH CONTRAST

+4531 [REDACTED] CT CHEST WITH CONTRAST

HISTORY:

Malignant melanoma.

FINDINGS:

Contrast-enhanced axial images of the chest were obtained with comparison to [REDACTED] +4420

For findings regarding the upper abdomen, please see the patient's abdominal and pelvis CT of the same date.

No acute bony abnormalities are identified. There are no new osteolytic or osteoblastic bony lesions. The thoracic aorta is not enlarged. A left subclavian Port-A-Catheter is in place with its tip in the superior vena cava.

Visualized portions of the thyroid gland appear normal. The heart is not enlarged. There is no evidence of a pericardial effusion. No new or progressive mediastinal or hilar adenopathy is identified. A few small stable appearing left axillary lymph nodes are noted. There are surgical clips in the right axilla. Stable soft tissue thickening of the right axilla is observed in this patient who is unable to raise her right arm. The remainder of the surrounding thoracic soft tissues appear stable.

[REDACTED]

[page 19 of 45]
100

- [REDACTED]

[page 20 of 45]
Results

CT ABD PELVIS WITH CONTRAST (Accession# [REDACTED])
WITH CONTRAST [REDACTED]

CT CHEST [REDACTED]

Admit Date: [REDACTED] +4588
Disch Date: [REDACTED]
Accession [REDACTED]

CT ABD PELVIS WITH CONTRAST

[REDACTED] CT STUDY ABDOMEN AND PELVIS WITH CONTRAST:

INDICATION:

Malignant melanoma.
+4588

The study date is [REDACTED] Axial and coronal images are submitted.

Since the last study, no focal liver abnormalities have developed. The spleen measures 10.5 cm in length. No splenic masses are present. The stomach, the pancreas, the right kidney and both adrenal glands are normal. There is a stable 10 x 10-mm fat-containing lesion in the left kidney consistent with an angiomyolipoma. In addition, there is a stable hypodensity in the right kidney likely representing a cyst.

No pathologically enlarged lymph nodes have developed in the abdomen or the pelvis. No bowel obstruction is present. Large amounts of feces are present throughout the entire colon. No abdominal or pelvic ascites has developed. There are no adnexal masses. No osteolytic or osteoblastic lesions are present. A prior cholecystectomy has been performed. A stable 13 mm in diameter left paraaortic lymph node is present on image 2-82. Scattered sigmoid diverticula are present with no CT evidence of diverticulitis.

IMPRESSION:

1. There is a stable 10 x 10-mm left renal angiomyolipoma.

[page 21 of 45]
- [REDACTED]
2. No mass, new or progressive lymphadenopathy, bowel obstruction or ascites has developed since [REDACTED] +4531
3. The patient has had a prior cholecystectomy.

CT study of the chest will be dictated separately.

Appropriate radiation dose reduction devices and/or manual techniques for appropriate moderation of exposure were utilized.

[page 22 of 45]
Results

CT ABD PELVIS WITH CONTRAST (Accession# [REDACTED])

CT CHEST

WITH CONTRAST (Accession# [REDACTED])

Admit Date [REDACTED] +4588

Disch Date [REDACTED]

Accession [REDACTED]

CT CHEST WITH CONTRAST

+4588 [REDACTED] CT CHEST WITH CONTRAST:

INDICATION:

Malignant melanoma. +4588

The study date is [REDACTED] The exam is compared to the [REDACTED] +4531 examination.

Since the last examination, no axillary, hilar, or mediastinal lymphadenopathy has developed. No pleural or pericardial effusions have developed. There are no focal areas of pneumonia. No pneumothorax is present. Visualized portions of the thyroid gland are normal.

Vascular clips are present in the right axilla. The patient is unable to raise her right arm. There is stable soft tissue thickening in the right axillary region.

Stable soft tissue thickening in the right lung apex is present. There is a stable nodular density in the left major fissure on image [REDACTED] It measures 7 mm in transverse x 2 mm in AP dimension.

There is a stable 2 x 2-mm nodule in the left upper lobe on image [REDACTED] No new pulmonary nodules have developed. Linear bibasilar atelectasis or scar is stable. Pleural thickening in the right posterior lung base is unchanged.

[page 23 of 45]
[REDACTED]

The patient has a Port-A-Catheter with its tip in the superior vena cava.

IMPRESSION:

1. There is a stable 2 x 2-mm nodule in the left upper lobe; there is a stable nodule in the left major fissure.
2. Stable pleural thickening is present in the posterior right lung base.
3. No new or progressive lymphadenopathy has developed since [REDACTED]
4. No pleural or pericardial effusions have developed. There is no pneumothorax.
5. Stable soft tissue thickening is present in the right axilla.

CT study of the abdomen and pelvis will be dictated separately.

Appropriate radiation dose reduction devices and/or manual techniques for appropriate moderation of exposure were utilized.

[REDACTED]

+4531

[page 24 of 45]
Results

CT ABD PELVIS WITH CONTRAST

CT CHEST

WITH CONTRAST

Admit Date: [REDACTED] +4707

Disch Date: [REDACTED] +4707

Accession [REDACTED]

CT ABD PELVIS WITH CONTRAST

+4707 [REDACTED] ABDOMEN AND PELVIC CT

CLINICAL INDICATION:

Malignant melanoma.

IMAGING:

Images were obtained through the abdomen and pelvis following intravenous and oral contrast with delayed images through the urinary tract and coronal reformations.

Comparison is made with [REDACTED] +4588

Chest findings have been reported separately.

FINDINGS:

The gallbladder is absent with surgical clips in the gallbladder bed. The liver and spleen are normal. There is no adrenal mass. The pancreas is somewhat difficult to separate from adjacent bowel loops. No definite abnormality is evident. Again noted is an angiomyolipoma in the upper pole of the left kidney. There is another small, indeterminate, cortical mass in the anterior cortex of the left kidney, unchanged and measuring 1 cm. Small paraaortic nodes are unchanged. There is prominent vasculature and the left adnexal region. A paucity of intraabdominal fat decreases the sensitivity of the examination. There is fecal material throughout the colon.

[page 25 of 45]
IMPRESSION:

1. Angiomyolipoma left kidney and small indeterminate left renal mass suggestive of a cyst but too small to characterize, unchanged.
2. Cholecystectomy.
3. Prominent vessels in the left adnexal region. Pelvic congestion syndrome could be considered.
4. Small paraaortic nodes, unchanged.
5. Constipation.

Appropriate radiation dose reduction devices and/or manual techniques for appropriate moderation of exposure were utilized.

[page 26 of 45]
Results

**CT ABD PELVIS WITH CONTRAST (Accession# [REDACTED])
WITH CONTRAST [REDACTED]**

CT CHEST

Admit Date: [REDACTED] +4707

Disch Date: [REDACTED] +4707

Accession [REDACTED]

CT ABD PELVIS WITH CONTRAST

ABDOMEN AND PELVIC CT

CLINICAL INDICATION:

Malignant melanoma.

IMAGING:

Images were obtained through the abdomen and pelvis following intravenous and oral contrast with delayed images through the urinary tract and coronal reformations.

Comparison is made with [REDACTED] +4588

Chest findings have been reported separately.

FINDINGS:

The gallbladder is absent with surgical clips in the gallbladder bed. The liver and spleen are normal. There is no adrenal mass. The pancreas is somewhat difficult to separate from adjacent bowel loops. No definite abnormality is evident. Again noted is an angiomyolipoma in the upper pole of the left kidney. There is another small, indeterminate, cortical mass in the anterior cortex of the left kidney, unchanged and measuring 1 cm. Small paraaortic nodes are unchanged. There is prominent vasculature and the left adnexal region. A paucity of intraabdominal fat decreases the sensitivity of the examination. There is fecal material throughout the colon.

[page 27 of 45]
IMPRESSION:

1. Angiomyolipoma left kidney and small indeterminate left renal mass suggestive of a cyst but too small to characterize, unchanged.
2. Cholecystectomy.
3. Prominent vessels in the left adnexal region. Pelvic congestion syndrome could be considered.
4. Small paraaortic nodes, unchanged.
5. Constipation.

Appropriate radiation dose reduction devices and/or manual techniques for appropriate moderation of exposure were utilized.

[page 28 of 45]
Results

CT ABD PELVIS WITH CONTRAST (

CT CHEST

WITH CONTRAST

Admit Date: +4707

Disch Date: +4707

Accession

CT CHEST WITH CONTRAST

+4707

CHEST CT

CLINICAL INDICATION:

Malignant melanoma, chemotherapy.

IMAGING:

Enhanced images were obtained through the chest.

Comparison is made with +4588

FINDINGS:

A 5.8 x 2.9-mm soft tissue density adjacent to the major fissure on the left on image 35 does not appear to have changed. There is a tiny, 1.6-mm opacity in the left upper lobe on image 28, unchanged. There is pleural thickening at the right apex and in the right costophrenic angle. There is a right lower rib fracture laterally, not definitely evident on the previous examination. There is no mediastinal mass or adenopathy. There is calcification in the right axilla. There is axillary asymmetry due to the patient's right arm not being raised.

IMPRESSION:

1. The 2 small opacities in the left lung are unchanged.
2. Pleural thickening on the right.
3. Right lower rib fracture, which may be new.
4. Calcifications in the right axilla, unchanged.

[page 29 of 45]
[REDACTED]

Appropriate radiation dose reduction devices and/or manual techniques for appropriate moderation of exposure were utilized.

[REDACTED]

[REDACTED]

[REDACTED]

[page 30 of 45]
Results CT ABD PELVIS WITH CONTRAST (Accession# [REDACTED]) (Order [REDACTED]) CT CHEST
WITH CONTRAST (Accession# [REDACTED]) (Order [REDACTED])

RADIOLOGY CT REPORT

Name: [REDACTED]
Address: [REDACTED]
Telephone: [REDACTED]
CSN: [REDACTED]
HAR: [REDACTED]
MR#: [REDACTED]
Order: [REDACTED]
DOB: [REDACTED]
Pt. Class: Outpatient/[REDACTED]
ROOM: [REDACTED]
Att. Phys: [REDACTED]
Ord. Phys: [REDACTED]
Insurance: [REDACTED]

Admit Date: [REDACTED] +4823

Disch Date: [REDACTED]

Accession [REDACTED]

CT ABD PELVIS WITH CONTRAST

+4823

[REDACTED] CT STUDY ABDOMEN AND PELVIS WITH CONTRAST:

INDICATION:

Malignant melanoma/chemotherapy.

+4828

+4707

The study date is [REDACTED] Comparison exam [REDACTED]

Since the last examination, no liver masses have developed. The spleen is unremarkable. There is a stable fat-containing lesion in the left kidney compatible with an angioliipoma. A subcentimeter hypodense lesion in the mid cortex of the left kidney is also stable and likely represents a cyst. The right kidney is unremarkable. No adrenal gland masses have developed. The paucity of intra-abdominal fat makes evaluation difficult; however, no discrete pancreatic mass is demonstrated. No pathologically enlarged lymph nodes have developed in the abdomen or the pelvis since the last examination. No bowel obstruction is present. The gallbladder is absent.

Since the last examination, bilateral ovarian cysts have developed. In the right ovary, the cyst measures 2.1 x 2.2 cm on image [REDACTED]. In the left ovary, the cyst measures 1.5 cm in transverse x 1.8 cm in AP dimension image [REDACTED]. Large amounts of fecal material are present in the colon with no bowel obstruction present.

[page 31 of 45]
[REDACTED]

The bone windows demonstrate no osteolytic or osteoblastic lesions. There is a stable punctate sclerotic focus in the left ischium and 1 the right femoral head compatible with bone islands.

IMPRESSION:

1. No mass, lymphadenopathy, bowel obstruction or ascites has developed since the prior study.
2. Stable fat-containing lesion in the left kidney compatible with an angiomyolipoma.
3. Prior cholecystectomy.
4. Stable prominence of the vessels in the left adnexal region.
5. Bilateral ovarian cysts.

Appropriate radiation dose reduction devices and/or manual techniques for appropriate moderation of exposure were utilized.

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[page 32 of 45]
Results

CT ABD PELVIS WITH CONTRAST

CT CHEST

WITH CONTRAST

(Order

Admit Date: +4823

Disch Date:

Accession

CT CHEST WITH CONTRAST

CT CHEST WITH CONTRAST

INDICATION:

Malignant melanoma on chemotherapy.

The comparison study is +4707

FINDINGS:

5 mm axial sections were obtained through the chest following IV contrast administration.

The thyroid gland is unremarkable. The trachea is midline in location. Since the last examination no axillary, hilar, or mediastinal lymphadenopathy has developed.

Right apical pleural thickening is stable. The patient has a Port-A-Catheter via left subclavian approach. Since the last examination, no pleural or pericardial effusions have developed.

Pleural thickening along the right lateral lung base is stable. The nodule in the left major fissure on image 3 to 36 is unchanged. No new pulmonary nodules have developed since the last examination.

Linear bibasilar scarring and dependent atelectasis is present. A right tenth rib fracture is present not seen with certainty on the prior

[page 33 of 45]
[REDACTED]

exam. An unchanged right eighth rib fracture is present.

IMPRESSION:

1. Stable pleural thickening in the right apex and right lateral lung base.
2. Stable nodule in the left major fissure. No other pulmonary nodules are demonstrated on the current exam.
3. No pleural or pericardial effusions have developed since [REDACTED] +4707
4. No axillary, hilar, or mediastinal lymphadenopathy has developed.
5. Nondisplaced right tenth rib fracture is not readily apparent on the prior examination. There is an unchanged right eighth rib fracture.

Appropriate radiation dose reduction devices and/or manual techniques for appropriate moderation of exposure were utilized.

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[page 34 of 45]
Results

CT ABD PELVIS WITH CONTRAST (Accession# [REDACTED] Order [REDACTED] CT CHEST
WITH CONTRAST (Accession# [REDACTED] Order [REDACTED])

Admit Date: [REDACTED] +5007

Disch Date:

Accession [REDACTED]

CT ABD PELVIS WITH CONTRAST

+5007 [REDACTED] CT SCAN OF THE ABDOMEN AND PELVIS WITH IV AND ORAL
CONTRAST:

HISTORY:

Anemia and malignant melanoma.

Compared to [REDACTED] +4823

FINDINGS:

No masses are seen within the liver, the spleen or the pancreas. The patient is postcholecystectomy. There is mild intrahepatic biliary duct dilatation. The common bile duct is not dilated.

The right and left adrenal gland is normal. Both kidneys enhance and excrete IV contrast. There is a fat-containing lesion upper pole left kidney which is unchanged, and there is a hypodense lesion midpole of the left kidney which is unchanged. There is no hydronephrosis or hydroureter bilaterally and no renal masses seen on the right side. There is no aortic aneurysm present.

There are lymph nodes seen in the retroperitoneal and periaortic region which are unchanged. There are no dilated loops of large or small intestine.

Follicles are seen within right and left ovaries. Prominent vascular

[page 35 of 45]
[REDACTED]

structures are seen within right and left broad ligament, greater on the left than the right side. No uterine masses.

IMPRESSION:

1. There are no dilated loops of large or small intestine.
2. There are small lymph nodes seen within retroperitoneal/periaortic region; some of these are greater than 1 cm in size. This is unchanged from the previous exam. No pelvic masses.

Appropriate radiation dose reduction devices and/or manual techniques for appropriate moderation of exposure were utilized.

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[page 36 of 45]
Results

CT ABD PELVIS WITH CONTRAST (Accession# [REDACTED]) (Order [REDACTED]) CT CHEST
WITH CONTRAST (Accession# [REDACTED]) (Order [REDACTED])

Admit Date: [REDACTED] +5007

Disch Date: [REDACTED]

Accession [REDACTED]

CT CHEST WITH CONTRAST

+5007 [REDACTED] CT SCAN OF THE CHEST WITH IV CONTRAST:

Compared to [REDACTED] +4823

HISTORY:

Malignant melanoma.

No previous study is available for comparison.

FINDINGS:

+4823 There is coarse calcification seen within the right axilla that is [REDACTED] +4260
unchanged from [REDACTED] but has progressed from [REDACTED] and
[REDACTED] This is probably dystrophic calcifications related to prior
+4420 surgery and radiation. There is a prominent lymph node in the right
upper hilum on image 25 which is unchanged from the previous exam. No
new lymph nodes are seen within the mediastinum and hila. There is no
pericardial effusion present. Thoracic aorta is not dilated.

There is no pleural effusion present. There is fibrosis in the
posterior aspect of the right upper lung and within right lower lung
which is unchanged. There is mild fibrosis or atelectasis left lower
lung. No new lung findings are seen. Old rib fractures are seen right
hemithorax which are unchanged.

IMPRESSION:

[page 37 of 45]
-
1. There are no new findings. No lymphadenopathy or evidence of metastatic disease.
2. Dystrophic calcification right axilla unchanged.

Appropriate radiation dose reduction devices and/or manual techniques for appropriate moderation of exposure were utilized.

[page 38 of 45]
Results

CT ABDOMEN PELVIS WITH CONTRAST (Accession# [REDACTED]) (Order [REDACTED])

Admit Date: [REDACTED] +5362

Disch Date: [REDACTED] +5362

Accession [REDACTED]

CT ABDOMEN PELVIS WITH CONTRAST

+5362 [REDACTED] CT OF THE ABDOMEN AND PELVIS WITH IV CONTRAST AND
ORAL CONTRAST
REFORMATTED IMAGES DONE ON NON-INDEPENDENT WORK STATION

HISTORY:

+5007 Malignant melanoma. The liver and spleen appear unremarkable. Adrenal glands are normal. Angiomyolipoma left kidney seen, unchanged from previous examination [REDACTED] A small low dense lesion likely a tiny cyst below CT resolution is seen, unchanged. No para-aortic adenopathy demonstrated. Gallbladder has been removed. No pancreatic abnormality is seen. No pelvic masses or adenopathy. No free fluid is demonstrated.

IMPRESSION:

1. Angiomyolipoma left kidney unchanged.
2. Small low dense lesion left kidney below CT resolution, unchanged. It is similar to [REDACTED] +4260
3. A previous cholecystectomy.

Appropriate radiation dose reduction devices and/or manual techniques for appropriate moderation of exposure were utilized.

[page 39 of 45]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[page 40 of 45]
Results

CT CHEST WITH CONTRAST (Accession# [REDACTED] (Order [REDACTED])

Admit Date: [REDACTED] +5362

Disch Date: [REDACTED] +5362

Accession [REDACTED]

CT CHEST WITH CONTRAST

+5362 [REDACTED] CT OF THE CHEST IV CONTRAST

HISTORY:

Myeloma.

+4260 There is a 4-mm nodule identified on image 24 unchanged dating back to [REDACTED]. Lungs are otherwise clear of infiltrate. No mediastinal or axillary adenopathy is demonstrated. There are calcification right axilla unchanged from previous examination.

Multiple right-sided healing rib fractures are identified, similar to previous exam.

IMPRESSION:

1. Tiny nodule identified left lung unchanged from [REDACTED] ~4260
2. Calcification right axilla again noted.
3. Multiple right-sided healing rib fracture.

Appropriate radiation dose reduction devices and/or manual techniques for appropriate moderation of exposure were utilized.

[page 41 of 45]
[REDACTED]

[REDACTED]

[REDACTED]

[page 42 of 45]
Results

CT ABDOMEN PELVIS WITH CONTRAST (Accession# [REDACTED]) (Order [REDACTED])

Admit Date: [REDACTED] +5719

Disch Date: [REDACTED] +5719

Accession:

CT ABDOMEN PELVIS WITH CONTRAST

+5719

[REDACTED] **CT SCAN OF THE ABDOMEN AND PELVIS WITH IV AND ORAL CONTRAST**

HISTORY:

Malignant melanoma.

Compared to [REDACTED] +5362

FINDINGS:

No masses are seen within the spleen or the pancreas. There is no pancreatic ductal dilatation. No masses are seen within the liver. The patient is status post cholecystectomy. There is mild intrahepatic biliary duct dilatation. The common bile duct is not dilated.

The right and left adrenal glands are normal. Both kidneys enhance and excrete IV contrast. There is no hydronephrosis or hydroureter. There is an angiomyolipoma upper pole left kidney, unchanged. There are other hypodense lesions in the left kidney that are unchanged.

There is no aortic aneurysm present. No retroperitoneal or para-aortic lymphadenopathy is noted.

Stool is seen throughout the colon. There is no evidence of colitis. No small bowel obstruction is seen. No pelvic masses are noted. There is possible mild uterine prolapse. Would correlate with physical exam. No uterine or ovarian masses are seen.

IMPRESSION:

1. No evidence of metastatic disease. No lymphadenopathy.
2. Angiomyolipoma upper pole left kidney, unchanged.

[page 43 of 45]
[REDACTED]

Appropriate radiation dose reduction devices and/or manual techniques for appropriate moderation of exposure were utilized.

[REDACTED]

[REDACTED]

[page 44 of 45]
Results

CT CHEST WITH CONTRAST (Accession#

(Order

Admit Date: +5719

Disch Date: +5719

Accession:

CT CHEST WITH CONTRAST

+5719 CT SCAN OF THE CHEST WITH IV CONTRAST

HISTORY:

Followup on malignant melanoma.

Compared to +5362

FINDINGS:

There is no mediastinal or hilar lymphadenopathy. No pericardial effusion is seen. Thoracic aorta is normal. No pleural effusion is identified. There is a 2 to 3 mm in size nodule left upper lung which is unchanged from the previous exam. This was reportedly unchanged dating back to . No new pulmonary nodule is seen. There is no consolidation. Old rib fractures are seen right hemithorax.

IMPRESSION:

Pulmonary nodule left upper lung, unchanged. No new pulmonary nodules. No evidence of metastatic disease or lymphadenopathy.

Appropriate radiation dose reduction devices and/or manual techniques for appropriate moderation of exposure were utilized.

[page 45 of 45]
[REDACTED]

on

[REDACTED]

+5720

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 5971e8c8-b699-46b7-8f55-6b3c435f6604 (ER0099 ER-ABEA Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).